Somatic mutation profile of tumor specimen C3N-01369-01 (aliquot CPT0162020006) from CPTAC case C3N-01369, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 57.5 years (21,015 days).
Specimen C3N-01369-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1d64c2b-93be-496f-bf5d-ed3622165a58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01369-31 (Blood Derived Normal), aliquot CPT0162040002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3424eecb-3f05-4281-a231-333b7448a510

The open-access MAF lists 54 somatic variants for this specimen: 43 protein-altering or splice-affecting, 9 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 9, 3'UTR 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 265/455 reads (58%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRB3 | c.3518C>T p.S1173F | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.523); catalogued as rs868010056, COSV53240104, COSV99484539; called by muse, mutect2
- ARSL | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as rs779945606, COSV66965257; called by muse, mutect2
- BEND2 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 13/226 reads (6%) | catalogued as COSV66216378; called by muse, mutect2
- C7orf33 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1176681066; called by muse, mutect2
- COL21A1 | c.1567C>A p.P523T | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV55157643; called by muse, mutect2
- CYP7A1 | c.451C>T p.R151C | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs201114135, COSV56964884; called by muse, mutect2, varscan2
- FMR1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782759579; called by muse, mutect2
- IL17RA | c.256C>A p.Q86K | Missense Mutation (SNP) | VAF 25/357 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV100083216; called by muse, mutect2
- JAG2 | c.1399G>A p.G467R | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs780937932; called by muse, mutect2
- LUZP2 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV61209632; called by muse, varscan2
- NLRP11 | c.2723C>A p.S908Y | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.76); catalogued as rs1282819393; called by muse, mutect2
- OR2T3 | c.51C>A p.F17L | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100613244; called by mutect2, varscan2
- OR4B1 | c.823G>A p.V275I | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.578); catalogued as rs377561605, COSV58882198; called by muse, mutect2
- P2RY2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.49); catalogued as rs751836374, COSV60776807; called by muse, mutect2
- PRLR | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 12/227 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1197065260, COSV51495677; called by muse, mutect2
- SCUBE1 | c.2845G>C p.V949L | Missense Mutation (SNP) | VAF 16/197 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV62610234; called by muse, mutect2
- SLC5A5 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 23/417 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as rs368434203; called by muse, mutect2
- STRC | c.4621C>T p.R1541W | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV55853117; called by muse, mutect2
- TMPRSS11E | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs188581615, COSV59520029; called by muse, mutect2
- TUBB1 | c.741C>A p.N247K | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53888157; called by muse, mutect2
- ZIC3 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 18/302 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.986); catalogued as COSV99798333; called by muse, mutect2
- ABCC12 | c.3197T>C p.L1066P | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AHNAK2 | c.866A>G p.D289G | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- AR | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.265); called by muse, mutect2
- B4GALNT3 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 30/342 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.086); called by muse, mutect2
- CCDC22 | c.1340C>A p.S447Y | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CREB3L3 | c.772C>G p.Q258E | Missense Mutation (SNP) | VAF 22/542 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNHD1 | c.3359T>C p.L1120P | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); called by muse, mutect2
- DOT1L | c.620A>G p.K207R | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT tolerated (0.28); PolyPhen benign (0.324); called by muse, mutect2
- DPH5 | c.781C>A p.P261T | Missense Mutation (SNP) | VAF 15/284 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.811); called by muse, mutect2
- EPG5 | c.6434T>G p.L2145R | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ESCO1 | c.2070C>A p.D690E | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HCN1 | c.2388G>T p.E796D | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.005); called by muse, mutect2
- MUC12 | c.14981C>T p.T4994I (on ENST00000379442; = p.T4851I on NM_001164462.1) | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); called by muse, mutect2
- OR2T12 | c.635T>C p.I212T | Missense Mutation (SNP) | VAF 32/398 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2
- PLXNA3 | c.4082G>A p.R1361H | Missense Mutation (SNP) | VAF 11/255 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RBM22 | c.26C>T p.T9I | Missense Mutation (SNP) | VAF 15/328 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.547); called by muse, mutect2
- RTTN | c.6139G>C p.G2047R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SNX29 | c.928C>T p.P310S | Missense Mutation (SNP) | VAF 41/532 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); called by muse, mutect2
- SSH1 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 17/229 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ZNF622 | c.148C>G p.R50G | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZSCAN22 | c.313A>G p.I105V | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.071); called by muse, mutect2
- FAM120C | c.537G>T p.R179= | Silent (SNP) | VAF 12/264 reads (5%) | called by muse, mutect2
- KCNJ4 | c.621C>A p.G207= | Silent (SNP) | VAF 11/103 reads (11%) | called by muse, mutect2, varscan2
- PDZD4 | c.1860G>A p.P620= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV51248178; called by muse, mutect2
- PHC1 | c.2022C>T p.D674= | Silent (SNP) | VAF 8/118 reads (7%) | catalogued as rs1334295875; called by muse, mutect2
- RAB24 | c.555G>A p.K185= | Silent (SNP) | VAF 14/316 reads (4%) | called by muse, mutect2
- SERPINA6 | c.45C>T p.S15= | Silent (SNP) | VAF 22/243 reads (9%) | catalogued as rs768544398; called by muse, mutect2
- TEKT4 | c.519C>T p.N173= | Silent (SNP) | VAF 11/171 reads (6%) | catalogued as rs143966999; called by muse, mutect2
- TEX51 | c.102G>A p.Q34= | Silent (SNP) | VAF 17/164 reads (10%) | called by muse, mutect2
- TFAP2B | c.657G>T p.L219= | Silent (SNP) | VAF 24/292 reads (8%) | catalogued as COSV53829856; called by muse, mutect2
- NKD2 | c.*195G>A | 3'UTR (SNP) | VAF 6/35 reads (17%) | catalogued as rs547757661, COSV56894210, COSV99724253; called by muse, mutect2, varscan2
- RNU6-1178P | chr17:20895751 C>T | 5'Flank (SNP) | VAF 9/115 reads (8%) | catalogued as rs774595751, COSV100019031; called by muse, mutect2
